Somatic mutation profile of tumor specimen TCGA-IB-7893-01A (aliquot TCGA-IB-7893-01A-11D-2201-08) from TCGA case TCGA-IB-7893, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 64.9 years (23,703 days).
Specimen TCGA-IB-7893-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32180774-11df-45ed-b1f4-e5712a5d28c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-7893-10A (Blood Derived Normal), aliquot TCGA-IB-7893-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/835caf50-2ed0-4191-bea8-ed1b505d54e3

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 8, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ2 | c.1639C>T p.R547W (on ENST00000359125 / NM_172107.4; = p.R519W on NM_004518.6) | Missense Mutation (SNP) | VAF 87/724 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs796052650, CM131778, COSV60557310; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 30/152 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.761T>G p.I254S | Missense Mutation (SNP) | VAF 76/341 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330865474, CM151471, COSV52674699, COSV52714188, COSV52767322; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC45 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 19/271 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs767498757, COSV99596343; called by muse, mutect2
- CFAP299 | c.360T>A p.N120K | Missense Mutation (SNP) | VAF 91/558 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100811233; called by muse, mutect2, varscan2
- CFTR | c.3073G>A p.A1025T | Missense Mutation (SNP) | VAF 36/407 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99133607; called by muse, mutect2
- CNTN5 | c.2802C>A p.F934L | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV54279650, COSV99671494; called by muse, mutect2, varscan2
- CSGALNACT1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 42/542 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs1468518731, COSV100174384; called by muse, mutect2
- CYB5R3 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs371323516; called by muse, mutect2, varscan2
- DCSTAMP | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 250/866 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138578884; called by muse, mutect2, varscan2
- DOCK3 | c.3548G>A p.R1183H | Missense Mutation (SNP) | VAF 76/951 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs370436668; called by muse, mutect2
- DOCK4 | c.2308G>A p.V770M | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as rs746631549, COSV70236096; called by muse, mutect2
- DYNC2H1 | c.11347C>A p.H3783N | Missense Mutation (SNP) | VAF 25/486 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100517102; called by muse, mutect2
- FAT4 | c.10664C>T p.P3555L | Missense Mutation (SNP) | VAF 192/926 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100626896; called by muse, mutect2, varscan2
- KRT37 | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99845205; called by muse, mutect2
- LRP1B | c.2267A>T p.Y756F | Missense Mutation (SNP) | VAF 140/717 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.985); catalogued as COSV101249995, COSV101250852; called by muse, mutect2, varscan2
- LRP2 | c.4742G>A p.R1581Q | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as rs763963014, COSV99785893; called by muse, mutect2
- NRXN3 | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1312815727, COSV59823316; called by muse, mutect2
- OR4C6 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 114/607 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.317); catalogued as rs367948844, COSV58603115; called by muse, mutect2, varscan2
- TMEM18 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs969982865, COSV55244620; called by muse, mutect2
- TMX1 | c.445A>T p.M149L | Missense Mutation (SNP) | VAF 43/405 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100795889; called by muse, mutect2, varscan2
- TRPM4 | c.3191G>A p.R1064H | Missense Mutation (SNP) | VAF 155/656 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.092); catalogued as COSV99418729; called by muse, mutect2, varscan2
- UBQLN2 | c.626C>G p.P209R | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100592597; called by muse, mutect2, varscan2
- WASL | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 46/521 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1319887205, COSV99771408; called by muse, mutect2
- ZHX3 | c.2797C>T p.R933C | Missense Mutation (SNP) | VAF 49/469 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.083); catalogued as rs148495510; called by muse, mutect2, varscan2
- ZMYND8 | c.3490G>A p.D1164N (on ENST00000311275 / NM_001363741.2; = p.D1138N on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/549 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs750833798, COSV53693981, COSV99519268; called by muse, mutect2, varscan2
- ZNF142 | c.5425C>T p.R1809C (on ENST00000411696 / NM_001379660.1; = p.R1609C on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/361 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs774221961, COSV68745848; called by muse, mutect2
- ZNF517 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.022); catalogued as rs961298456, COSV100743347; called by muse, mutect2
- ACSS3 | c.1581del p.F528Lfs*31 | Frame Shift Del (DEL) | VAF 21/182 reads (12%) | called by mutect2, pindel, varscan2
- AGBL2 | c.2493A>T p.S831= | Silent (SNP) | VAF 144/1630 reads (9%) | catalogued as COSV100101052; called by muse, mutect2
- AMPD3 | c.1464C>T p.N488= (on ENST00000396553 / NM_001025389.2; = p.N497= on NM_000480.3) | Silent (SNP) | VAF 46/628 reads (7%) | catalogued as COSV101158064; called by muse, mutect2
- DAGLB | c.1032C>T p.F344= | Silent (SNP) | VAF 76/403 reads (19%) | catalogued as COSV99765600; called by muse, mutect2, varscan2
- LRP11 | c.780A>G p.Q260= | Silent (SNP) | VAF 49/403 reads (12%) | catalogued as rs201434283; called by muse, mutect2, varscan2
- NUDT14 | c.606C>T p.L202= | Silent (SNP) | VAF 35/327 reads (11%) | catalogued as rs1261607060, COSV100077761; called by muse, mutect2, varscan2
- PNLIP | c.873C>T p.I291= | Silent (SNP) | VAF 83/777 reads (11%) | catalogued as rs1235393329, COSV100981577; called by muse, mutect2, varscan2
- SULT1C2 | c.351G>A p.P117= | Silent (SNP) | VAF 135/743 reads (18%) | catalogued as rs950292534, COSV52265060, COSV99264923; called by muse, mutect2, varscan2
- ZNF493 | c.597C>T p.G199= | Silent (SNP) | VAF 26/377 reads (7%) | catalogued as COSV100828498; called by muse, mutect2
- PRRX1 | c.599+3922G>A | Intron (SNP) | VAF 184/1262 reads (15%) | catalogued as rs148536447; called by muse, mutect2, varscan2
